Somatic mutation profile of tumor specimen C3N-02996-02 (aliquot CPT0187820034) from CPTAC case C3N-02996, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.0 years (28,479 days).
Specimen C3N-02996-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69997f30-8601-4142-9b64-406393a6e5d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02996-31 (Blood Derived Normal), aliquot CPT0187870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf506b8-2ebf-424e-97c6-eac0d8a0ed4a

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Intron 3, Nonsense Mutation 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 55/240 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 101/522 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778031362, COSV53623654; called by muse, mutect2, varscan2
- ADAMTS2 | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs574735794, COSV52368892; called by muse, mutect2, varscan2
- ANKRD33B | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs753983099; called by muse, mutect2, varscan2
- ATP10A | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as rs367580656, COSV63515642; called by muse, mutect2, varscan2
- GPR180 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745940659; called by muse, mutect2, varscan2
- KLF6 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 18/175 reads (10%) | catalogued as COSV51494748; called by muse, mutect2
- KRTAP8-1 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.05); catalogued as rs1156387848, COSV61598577; called by muse, mutect2, varscan2
- MAP2K2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV99502669; called by muse, varscan2
- NCAN | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs757000546, COSV53048696; called by muse, mutect2, varscan2
- PRPF31 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs373212857, COSV100320039; called by muse, mutect2, varscan2
- RFT1 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759915886; called by muse, mutect2, varscan2
- SULF2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759624061, COSV63416865, COSV63417492; called by muse, mutect2, varscan2
- TRIM64C | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73267312, COSV73267459; called by muse, mutect2, varscan2
- BPTF | c.6434G>A p.S2145N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CENPJ | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CWC25 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- HAS1 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT20 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MAGEC3 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- MAGT1 | c.129_136del p.L44Mfs*3 (on ENST00000618282 / NM_001367916.1; = p.L76Mfs*3 on NM_032121.5) | Frame Shift Del (DEL) | VAF 30/323 reads (9%) | called by mutect2, pindel
- MAP2K2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, varscan2
- MTMR3 | c.86A>C p.N29T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC1A3 | c.1549A>T p.N517Y | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- USP43 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- ZNF438 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- CAVIN3 | c.468G>A p.E156= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- EHBP1L1 | c.1449G>A p.A483= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs746365198; called by muse, mutect2, varscan2
- JAKMIP1 | c.2196C>T p.A732= | Silent (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2
- KLHL10 | c.936C>T p.D312= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs782377797, COSV99509497; called by muse, mutect2
- MAP2K2 | c.543G>A p.L181= | Silent (SNP) | VAF 79/501 reads (16%) | catalogued as rs1218585349; called by muse, mutect2, varscan2
- MAP2K2 | c.477G>A p.L159= | Silent (SNP) | VAF 93/525 reads (18%) | catalogued as rs748135585; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCOLCE | c.417A>T p.G139= | Silent (SNP) | VAF 83/475 reads (17%) | called by muse, mutect2, varscan2
- PCSK2 | c.1629C>T p.D543= | Silent (SNP) | VAF 37/265 reads (14%) | catalogued as rs1292802589, COSV52739182; called by muse, mutect2, varscan2
- TAAR2 | c.282C>T p.F94= (on ENST00000367931 / NM_001033080.1; = p.F49= on NM_014626.3) | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- TBKBP1 | c.798G>A p.E266= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- TUBGCP3 | c.1839C>T p.D613= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as rs1442434130; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1571C>T | Intron (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- FMN2 | c.1930+2102G>A | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- KAZALD1 | chr10:101067949 C>T | 3'Flank (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.579-56G>C | Intron (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
